Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5K2, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5K2-01A (Primary Tumor).

[page 1 of 4]
PAT TYPE:

PAGE #: 1
SEX: F
ADM DATE:

OPER DATE:

PROCEDURE: APM1

ADDENDUM REPORT FOLLOWING DISCUSSION WITH THE SURGEON:

=====

After discussing the margin status with the surgeon it is clear that the previously reported positive surgical margin is in fact not a true margin. Following removal of the tumor, a small capsular defect was noted at the superior aspect and this was felt to be iatrogenically induced. No tumor spillage resulted from this and the tumor was clearly covered by a glistening unremarkable capsule following removal. Therefore, please see revised template and diagnosis below.

ADRENOCORTICAL CARCINOMA
V3

Tumor Size: 14.5 x 11 x 7.9 cm.

Tumor Weight: 560 grams.

Capsular Invasion: Present.

Vascular Invasion: Present.

Surgical Margins: Negative.

Necrosis: Present (20%).

Mitotic Rate: 51/50 high power field.

Grade: High-grade.

Lymph nodes status: 0/1.

Extra-adrenal Extension: Present.

Stage: pT4 NX MX

PROCEDURE: APDX

2. Right adrenal gland and vena cava, resection: High-grade adrenocortical carcinoma (560 gram, 14.5 cm), completely excised. Extensive vascular invasion including venous invasion within periadrenal soft tissues. Please see template for details.

1 and 3-5. Please see previous report for diagnosis which remains unchanged.

ICD-O-3
Carcinoma, adrenal cortical 8376/3
Site: Adrenal Gland cortex 874.0
4/2 1/30/13

[page 2 of 4]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: F
ADM DATE:

BIRTHDATE: _____

PAI TYPE: _____

OPER DATE: _____

the signing staff pathologist, have personally examined and interpreted the slides from this case.

PROCEDURE: SPHS

Testosterone producing adrenal cortical carcinoma and vena cava thrombosis extending to chest. Also has history of multinodular goiter for four years. 14 cm right adrenal mass, 20 lb weight loss over two months, lung nodule, liver mass, IVC thrombus.

PROCEDURE: SPGD

1. "Peritoneal implant". A 0.2 cm soft tissue fragment.
- 1A. Frozen section control.
2. "Right adrenal tumor and vena cava thrombus". Received in formalin in a large container is a 560 gram, 14.5 cm superior to inferior x 11.0 cm medial to lateral x 7.9 cm anterior to posterior resection specimen which was received fresh for procurement. Specimen is oriented as follows: Two long inferior, two short superior, one long lateral, two medial vena cava thrombus, two extra long anterior. The external surface of the resection specimen is smooth and the resection specimen is composed almost entirely of tumor. Cut surfaces are pink-tan with foci of bright yellow streaking through the tumor. A small amount of residual identifiable adrenal gland is present, however, there are no definitive areas of gross necrosis. There are possible lymph nodes in the periadrenal as well as near the vascular insertions.
- 2A-B. Lateral margin.
- 2C-D. Anterior margin.
- 2E. Tumor near stitch for vena cava thrombus
- 2F-G. Medial margin.
- 2H-I. Inferior margin, serially sectioned.
- 2J-K. Radial sections to superior margin.
- 2L. Representative sections of posterior margin.
- 2M-N. Periadrenal lymph nodes.
- 2O-R. Central portion of mass.
3. "Vena cava margin". Received in formalin in a small container is a 1.2 x 0.6 x 0.2 cm portion of soft tissue. Entirely submitted in one cassette.

[page 3 of 4]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 3
SEX: F
ADM DATE:

BIRTHDATE:

PAT TYPE:

OPER DATE:

4. "Periadrenal tissue" Received in formalin in a small container is a 1.1 x 0.7 x 0.2 cm portion of soft tissue. Entirely submitted in one cassette.
5. "Gallbladder" Received in formalin in a small container is a 5.4 x 2.4 x 1.3 cm gallbladder. Serosal surface is grossly unremarkable. Wall thickness is unremarkable at 0.1 cm. Luminal contents consists of green bile. No stones identified. Mucosal surfaces grossly unremarkable.
- 5A. Cystic duct in artery and representative section of cystic wall.

FROZEN SECTION REPORT

1. Papillary mesothelial proliferation. Negative for carcinoma.

have reviewed and interpreted the frozen section requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPMI

ADRENOCORTICAL CARCINOMA
V3

Tumor Size: 14.5 x 11 x 7.9 cm

Tumor Weight: 560 gm

Capsular Invasion: Present

Vascular Invasion: Present

Surgical Margins: Positive (superior)

Necrosis: Present (20%)

Mitotic Rate: 51/50 high power field

Grade: High grade

Lymph nodes status: 0/1

Extra-adrenal Extension: Present

Stage: pT4 NX MX

[page 4 of 4]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 4
SEX: F
ADM DATE:

BIRTHDATE:

TYPE:

OPER DATE:

PROCEDURE: SPDX

1. Peritoneum, biopsy: Papillary mesothelial hyperplasia. Negative for carcinoma.
2. Right adrenal gland and vena cava, resection: High grade adrenocortical carcinoma (560 gm, 14.5 cm), extending to the superior margin. Extensive vascular invasion. Please see template for details.
3. Vena cava, margin, excision: Detached fragment of adrenocortical carcinoma. No carcinoma in vein wall.
4. Periadrenal soft tissue, resection: One lymph node negative for carcinoma.
5. Gallbladder, resection: No significant abnormality.

The signing staff pathologist, have personally examined and interpreted the slides from this case.

** END OF PREVIOUS DIAGNOSIS INQUIRY **

Criteria	12/22/12	Yes	No
Dual/Synchronous Malignancy Noted			

Source: NCI Genomic Data Commons file a803bf5d-65cd-4988-9209-6500a9852ec4 (TCGA-OR-A5K2.F6CEA42D-A107-4942-B6FE-1C529D124337.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).